CPTAC case C3L-03266 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f8ced7cc-1962-4825-b63e-da8a1fb42cf2

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1956; Vital status: Dead; Days to death: 281 days; Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 61.8 years (22,583 days); Year of diagnosis: 2017; Days to last known disease status: 281 days; Progression or recurrence: no; Days to last follow up: 223 days.
   Pathology details: Greatest tumor dimension: 2.2 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 223 days; Progression or recurrence: Yes; Days to recurrence: 28 days; Karnofsky performance status: 60; ECOG performance status: 2.

Other clinical attributes
- Weight: 65.77 kg; Height: 162.56 cm; BMI: 24.89.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 2.2; Cigarettes per day: 1; Tobacco smoking onset year: 1974; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 48.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03266-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 180 mg; Time between excision and freezing: 24 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03266-21: Section location: Parietal Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-03266-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
